Somatic mutation profile of tumor specimen TCGA-EE-A3J8-06A (aliquot TCGA-EE-A3J8-06A-11D-A20D-08) from TCGA case TCGA-EE-A3J8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 60.9 years (22,241 days).
Specimen TCGA-EE-A3J8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 304e995c-0cb5-4848-9328-fb5cd9fa127f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3J8-10A (Blood Derived Normal), aliquot TCGA-EE-A3J8-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c8f06a3-0ba1-4a4a-9db0-28f8314f62b0

The open-access MAF lists 323 somatic variants for this specimen: 212 protein-altering or splice-affecting, 105 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 190, Silent 105, Nonsense Mutation 13, Splice Region 4, Splice Site 4, Intron 4, Frame Shift Del 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 55/105 reads (52%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 149/267 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAK5 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 81/167 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769939031, COSV62021293; called by muse, mutect2, varscan2
- TP53 | c.400T>C p.F134L | Missense Mutation (SNP) | VAF 18/19 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267605077, COSV52660909, COSV52676112, COSV52697695, COSV52923862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.9760C>T p.R3254* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs941969577, COSV62155018; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.573C>T p.F191= | Splice Region (SNP) | VAF 9/25 reads (36%) | catalogued as rs374454045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVRL1 | c.1058T>G p.V353G | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66360958; called by muse, mutect2, varscan2
- ADAD1 | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV56642645; called by muse, mutect2, varscan2
- ADAM19 | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 109/120 reads (91%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV57438295; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1314T>G p.S438R | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58446253; called by muse, mutect2, varscan2
- ALDH1A2 | c.434A>T p.K145I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV51089652; called by muse, mutect2, varscan2
- ANKRD30A | c.964G>A p.E322K (on ENST00000611781; = p.E266K on NM_052997.2) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.292); catalogued as COSV64608757; called by muse, mutect2, varscan2
- APOBR | c.3025C>T p.R1009C (on ENST00000431282; = p.R1018C on NM_018690.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs528190355, COSV60489033; called by muse, mutect2
- ARHGAP33 | c.245T>G p.V82G | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV50155295; called by muse, mutect2, varscan2
- ARID4A | c.2605A>T p.I869L | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV62162019, COSV62163928, COSV62166290; called by muse, varscan2
- ARMC9 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63023202; called by muse, mutect2, varscan2
- ARMCX2 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 48/50 reads (96%) | catalogued as COSV57531071; called by muse, mutect2, varscan2
- ARMH4 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV99957384, COSV99959127; called by muse, mutect2, varscan2
- ASAP1 | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV63053816; called by muse, mutect2, varscan2
- ATG9B | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52495045; called by muse, mutect2, varscan2
- AXDND1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as COSV62647627; called by muse, mutect2, varscan2
- BATF2 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV57251178; called by muse, mutect2, varscan2
- BMP5 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63702572; called by muse, mutect2, varscan2
- C1R | c.848G>A p.G283E (on ENST00000536053 / NM_001354346.2; = p.G269E on NM_001733.7) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73293829; called by muse, mutect2, varscan2
- C5orf38 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs1432783445, COSV100121501; called by muse, mutect2, varscan2
- C6 | c.930T>C p.D310= | Splice Region (SNP) | VAF 9/19 reads (47%) | catalogued as COSV54717239; called by muse, mutect2, varscan2
- C8B | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64776698; called by muse, mutect2, varscan2
- CACNA1E | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as COSV100701094; called by muse, varscan2
- CAMK1D | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.229); catalogued as COSV66618785; called by muse, mutect2, varscan2
- CARM1 | c.1539G>A p.G513= | Splice Region (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99449705; called by muse, mutect2, varscan2
- CARM1 | c.1540A>C p.M514L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.558); catalogued as COSV99449706; called by muse, mutect2, varscan2
- CAVIN2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV58424145; called by muse, mutect2, varscan2
- CC2D2B | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV60359067; called by muse, mutect2, varscan2
- CCDC171 | c.3746T>C p.L1249S | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV66243550; called by muse, mutect2, varscan2
- CD163L1 | c.3899C>T p.S1300L | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs769558243, COSV58021014; called by muse, mutect2, varscan2
- CD3G | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.573); catalogued as COSV52676026; called by muse, varscan2
- CD80 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV99958075; called by muse, mutect2, varscan2
- CD80 | c.101-1G>A p.X34_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as rs1157705177, COSV99958078; called by muse, mutect2, varscan2
- CEACAM6 | c.465C>A p.N155K | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs537042421, COSV52269019; called by muse, mutect2, varscan2
- CELSR3 | c.7310C>T p.P2437L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1559477645, COSV51142082; called by muse, mutect2, varscan2
- CEP152 | c.4221C>A p.C1407* (on ENST00000380950 / NM_001194998.2; = p.C1351* on NM_014985.4) | Nonsense Mutation (SNP) | VAF 44/102 reads (43%) | catalogued as COSV57864160; called by muse, mutect2, varscan2
- CHI3L2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.4); catalogued as rs751231137, COSV63874210; called by muse, mutect2, varscan2
- CLTCL1 | c.2426C>T p.P809L | Missense Mutation (SNP) | VAF 114/249 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54238202, COSV54239471; called by muse, mutect2, varscan2
- CNTNAP4 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as COSV56698027, COSV56705357; called by muse, mutect2, varscan2
- COL14A1 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as rs757158066, COSV52866361; called by muse, mutect2, varscan2
- COL4A4 | c.3032G>A p.G1011E | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61631582; called by muse, mutect2, varscan2
- CPXM2 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV53863318; called by muse, mutect2, varscan2
- CSMD2 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs775463572, COSV53879418; called by muse, mutect2, varscan2
- CUL7 | c.3190C>T p.P1064S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.192); catalogued as rs1463305391, COSV54819098, COSV54821413; called by muse, mutect2, varscan2
- CXCR4 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV54016139, COSV54017107; called by muse, mutect2, varscan2
- CYTIP | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV51635715; called by muse, mutect2, varscan2
- DCAF4L2 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV60478173; called by muse, mutect2, varscan2
- DCSTAMP | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV52579841, COSV52579959; called by muse, mutect2, varscan2
- DEF8 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV51921145; called by muse, mutect2, varscan2
- DNAH5 | c.13780G>A p.D4594N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs760482011, COSV54248336; called by muse, mutect2, varscan2
- DNAH7 | c.4840G>A p.G1614R | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56770023; called by muse, mutect2, varscan2
- DSG1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs377729186; called by muse, mutect2, varscan2
- DSP | c.1976G>A p.R659K | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV65795400; called by muse, mutect2, varscan2
- EEFSEC | c.1264T>G p.C422G | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV54631978; called by muse, mutect2, varscan2
- ELMOD3 | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV59775523; called by muse, mutect2, varscan2
- ELOA2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as rs770458411, COSV55307526; called by muse, mutect2, varscan2
- ELP1 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV65899644; called by muse, mutect2, varscan2
- ENAM | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as COSV68535600; called by muse, mutect2, varscan2
- EPHB1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67669953; called by muse, mutect2, varscan2
- EPHB2 | c.232A>T p.I78F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65866168; called by muse, mutect2, varscan2
- ERN2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1419273101, COSV56837499; called by muse, mutect2, varscan2
- FASN | c.4751C>T p.S1584F | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as rs955022144, COSV60752610, COSV60760552; called by muse, mutect2, varscan2
- FNDC1 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.226); catalogued as rs267600879, COSV51944087; called by muse, mutect2, varscan2
- FRMD4B | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs768015246, COSV68333137; called by muse, mutect2, varscan2
- GADD45B | c.266T>A p.I89N | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53126696; called by muse, varscan2
- GAK | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs768962219, COSV58502921; called by muse, mutect2, varscan2
- GATM | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs147804855; ClinVar: not provided; called by muse, mutect2, varscan2
- GIT2 | c.2171C>T p.S724L (on ENST00000355312 / NM_057169.5; = p.S646L on NM_014776.5) | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs781492736, COSV58084546; called by muse, mutect2, varscan2
- GRM3 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.302); catalogued as COSV64478682, COSV64479915; called by muse, mutect2, varscan2
- GUCA1C | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1179553650, COSV53756034, COSV53756094, COSV99659956; called by muse, mutect2, varscan2
- H2AC1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as rs1418751341, COSV51237093, COSV99219604; called by muse, mutect2, varscan2
- HECW1 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67825458, COSV67829709; called by muse, mutect2, varscan2
- HEPHL1 | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV59895846; called by muse, mutect2, varscan2
- HIVEP2 | c.4264C>T p.P1422S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs752207024, COSV50050320; called by muse, mutect2, varscan2
- HRC | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53258597; called by muse, mutect2, varscan2
- HSPA6 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV59060020, COSV59062419; called by muse, mutect2, varscan2
- IGF2BP1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 59/60 reads (98%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV51731960; called by muse, mutect2, varscan2
- IGHV3-7 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs368555180; called by muse, mutect2, varscan2
- IL22RA1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 109/197 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0.03); catalogued as rs778001218, COSV54630205; called by muse, mutect2, varscan2
- IL37 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54490299; called by muse, mutect2, varscan2
- INO80D | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV68959923; called by muse, mutect2, varscan2
- IRGQ | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV60671402; called by muse, varscan2
- ITGAE | c.1927C>T p.Q643* | Nonsense Mutation (SNP) | VAF 33/36 reads (92%) | catalogued as COSV53999155; called by muse, mutect2, varscan2
- KCNK10 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as COSV56651558; called by muse, mutect2, varscan2
- KCNN1 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV55841831; called by muse, mutect2, varscan2
- KLF5 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs919174078, COSV66615433; called by muse, mutect2, varscan2
- KLHL30 | c.1578A>T p.E526D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV59978258; called by muse, mutect2, varscan2
- KMT2A | c.4963C>T p.R1655W | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373435126, COSV100628635, COSV63291939; called by muse, mutect2, varscan2
- LAIR2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV56622914; called by muse, mutect2, varscan2
- LBP | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV54143138; called by muse, mutect2, varscan2
- LMNTD2 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs775210406, COSV54246436; called by muse, mutect2, varscan2
- LMO3 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as COSV53783256, COSV99662475; called by muse, mutect2, varscan2
- LRFN5 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV53243340, COSV53258853; called by muse, mutect2, varscan2
- LRP1B | c.13643G>A p.G4548E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.65); PolyPhen probably damaging (0.994); catalogued as COSV67268012; called by muse, mutect2, varscan2
- LRSAM1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV55942419; called by muse, mutect2
- LSR | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61555500, COSV61555862; called by muse, mutect2, varscan2
- MAGEA4 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 78/79 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52342937; called by muse, mutect2, varscan2
- MFSD4A | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV65656437, COSV65657013; called by muse, mutect2, varscan2
- MKI67 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as COSV64076543; called by muse, mutect2, varscan2
- MLXIP | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs1319846898, COSV59837688; called by muse, varscan2
- MON1B | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1217746226, COSV99941419; called by muse, mutect2, varscan2
- MORC1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV51713955; called by muse, mutect2, varscan2
- MRM2 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV54249044; called by muse, mutect2, varscan2
- MROH2B | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.99); catalogued as rs759741202, COSV68182101; called by muse, mutect2, varscan2
- MTUS2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV70916745, COSV70921751; called by muse, mutect2, varscan2
- MUC16 | c.6311G>A p.R2104K | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs958654860, COSV67446402; called by muse, mutect2, varscan2
- MUC17 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 220/531 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1266993574, COSV60301297; called by muse, varscan2
- MYH4 | c.4492C>T p.H1498Y | Missense Mutation (SNP) | VAF 64/69 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV55121185, COSV55125044; called by muse, mutect2, varscan2
- NBEA | c.3382C>T p.P1128S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.992); catalogued as rs773783447, COSV59818043; called by muse, mutect2, varscan2
- NFAT5 | c.4168C>T p.Q1390* | Nonsense Mutation (SNP) | VAF 37/90 reads (41%) | catalogued as COSV63032142; called by muse, mutect2, varscan2
- NGEF | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1328957939, COSV50936950, COSV50950158; called by muse, mutect2, varscan2
- NLGN1 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs935435410, COSV64345137; called by muse, mutect2, varscan2
- NLRP5 | c.1620G>A p.W540* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV66767071; called by muse, mutect2, varscan2
- NPC1L1 | c.2855C>T p.S952F | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56929715; called by muse, mutect2, varscan2
- NPFFR2 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58148552; called by muse, mutect2, varscan2
- NPY5R | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV58453707; called by muse, mutect2, varscan2
- NUP210 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs780188310, COSV54413009; called by muse, mutect2, varscan2
- OR1L8 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs771093917, COSV59185779; called by muse, mutect2, varscan2
- OR5H14 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs541342101, COSV71193554, COSV71194506; called by muse, mutect2, varscan2
- OR5H2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770093101, COSV62350222, COSV62350448; called by muse, mutect2, varscan2
- OR6C6 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.012); catalogued as COSV64456177; called by muse, mutect2, varscan2
- OR8D1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs1029345414, COSV63441743, COSV63442931; called by muse, mutect2, varscan2
- PALLD | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54979667; called by muse, mutect2, varscan2
- PARP6 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99535630; called by muse, mutect2, varscan2
- PARP6 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99535633; called by muse, mutect2, varscan2
- PCDHA2 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs386352344, COSV65370677; called by muse, mutect2, varscan2
- PCDHAC1 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 85/93 reads (91%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs762916391, COSV53835909; called by muse, mutect2, varscan2
- PCDHB4 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV52026507; called by muse, mutect2, varscan2
- PCLO | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as COSV61661666; called by muse, mutect2, varscan2
- PDE3A | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV62981713; called by muse, mutect2, varscan2
- PKHD1L1 | c.4961G>A p.R1654Q | Missense Mutation (SNP) | VAF 128/267 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs373094487, COSV65747646; called by muse, mutect2, varscan2
- PLCXD3 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1339460173, COSV60606946, COSV60606965; called by muse, mutect2, varscan2
- POMT1 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 66/69 reads (96%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.005); catalogued as rs975217678, COSV57645460; called by muse, mutect2, varscan2
- POMT1 | c.486C>A p.F162L | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61227687; called by muse, mutect2, varscan2
- PRDM2 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV52454629; called by muse, mutect2, varscan2
- PRPF4B | c.2825A>C p.K942T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV61785558; called by muse, mutect2
- PSG6 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 161/576 reads (28%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.781); catalogued as COSV51837029; called by muse, mutect2, varscan2
- PTGFR | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT tolerated (0.91); PolyPhen benign (0.192); catalogued as COSV66116490; called by muse, mutect2, varscan2
- RANBP17 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.566); catalogued as COSV66656204; called by muse, mutect2, varscan2
- RAPGEF3 | c.1750G>A p.E584K (on ENST00000389212; = p.E542K on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as rs748055367, COSV50205209, COSV50232860; called by muse, mutect2, varscan2
- RELN | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as rs267601217, COSV58985849, COSV59014511; called by muse, mutect2, varscan2
- RETNLB | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs749789641, COSV55465198; called by muse, mutect2, varscan2
- ROBO2 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV100163019, COSV59950025; called by muse, mutect2, varscan2
- ROS1 | c.6465A>T p.L2155F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63861019; called by muse, mutect2, varscan2
- RP1 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs765035454, COSV55119696; called by muse, mutect2, varscan2
- RYK | c.1129C>T p.Q377* (on ENST00000620660 / NM_001005861.2; = p.Q374* on NM_002958.4) | Nonsense Mutation (SNP) | VAF 11/19 reads (58%) | catalogued as COSV56064171; called by muse, mutect2, varscan2
- SELE | c.715+1G>A p.X239_splice | Splice Site (SNP) | VAF 39/119 reads (33%) | catalogued as rs767331571, COSV60977529; called by muse, mutect2, varscan2
- SETD4 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs375159015; called by muse, mutect2, varscan2
- SHPRH | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV51616590; called by muse, mutect2, varscan2
- SIGLEC14 | c.1070T>G p.V357G | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.755); catalogued as COSV55783419; called by muse, mutect2, varscan2
- SIGLEC8 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV58475593; called by muse, mutect2, varscan2
- SLC1A5 | c.1604C>T p.S535F | Missense Mutation (SNP) | VAF 96/189 reads (51%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs763572985, COSV69467412; called by muse, mutect2, varscan2
- SLC22A25 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs190170249, COSV60596972; called by muse, mutect2, varscan2
- SLC25A23 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1367934212, COSV51196223; called by muse, mutect2, varscan2
- SLC2A2 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV58588366; called by muse, mutect2, varscan2
- SMOC2 | c.1111G>A p.E371K (on ENST00000356284 / NM_001166412.2; = p.E382K on NM_022138.3) | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62443754; called by muse, mutect2, varscan2
- SPOCK3 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs377199025; called by muse, mutect2, varscan2
- STRADB | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV52045612; called by muse, mutect2, varscan2
- SVEP1 | c.8425G>A p.G2809S | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253604337, COSV52841923; called by muse, mutect2, varscan2
- SYF2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1233724523, COSV52574331; called by muse, mutect2, varscan2
- TAOK2 | c.3527C>T p.A1176V | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as COSV54231612; called by muse, mutect2, varscan2
- TBC1D10C | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1457886017, COSV56704998; called by muse, mutect2, varscan2
- TBCCD1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1483264359, COSV58662568; called by muse, mutect2, varscan2
- TBL3 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.199); catalogued as rs1021687302, COSV60342940; called by muse, mutect2, varscan2
- TDO2 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV72233093; called by muse, mutect2, varscan2
- TECPR1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV65784968; called by muse, mutect2, varscan2
- TENM4 | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs757872169, COSV53664646; called by muse, mutect2, varscan2
- TESPA1 | c.1510C>T p.P504S (on ENST00000316577 / NM_001098815.3; = p.P366S on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/284 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as COSV57260995; called by muse, mutect2, varscan2
- THNSL1 | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 37/95 reads (39%) | catalogued as rs139395919, COSV64479199; called by muse, mutect2, varscan2
- TMEM109 | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs374688846, COSV50020403; called by muse, mutect2, varscan2
- TMEM178A | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56143288; called by muse, mutect2, varscan2
- TNFRSF8 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV55800248; called by muse, varscan2
- TNFSF18 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53439687; called by muse, mutect2, varscan2
- TNR | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 148/348 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as rs761891641, COSV54872398, COSV99686657; called by muse, mutect2, varscan2
- TNR | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 149/353 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99686659; called by muse, mutect2, varscan2
- TNRC18 | c.5341G>A p.G1781S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.469); catalogued as COSV101269467, COSV68163868; called by muse, mutect2, varscan2
- TNS2 | c.1276C>T p.P426S (on ENST00000314250 / NM_170754.4; = p.P436S on NM_015319.2) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV58581527; called by muse, mutect2, varscan2
- TOX | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63850070; called by muse, mutect2, varscan2
- TP63 | c.1747-1G>A p.X583_splice | Splice Site (SNP) | VAF 33/62 reads (53%) | catalogued as COSV53219261; called by muse, mutect2, varscan2
- TRAV22 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs267603936; called by muse, mutect2, varscan2
- TRIM61 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs142627348, COSV61417684; called by mutect2, varscan2
- TRIML2 | c.1120C>T p.L374F | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58719111; called by muse, mutect2, varscan2
- TRPC7 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT tolerated (0.83); PolyPhen benign (0.03); catalogued as rs753754845, COSV61462929; called by muse, mutect2, varscan2
- TRPM8 | c.2274G>A p.M758I | Missense Mutation (SNP) | VAF 232/558 reads (42%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.914); catalogued as COSV100224501, COSV61223921; called by muse, mutect2, varscan2
- TSPAN8 | c.336+1G>A p.X112_splice | Splice Site (SNP) | VAF 81/201 reads (40%) | catalogued as rs375743516, COSV56080253; called by muse, mutect2, varscan2
- TTN | c.102518G>A p.G34173E (on ENST00000591111; = p.G26749E on NM_003319.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | PolyPhen benign (0.015); catalogued as COSV60303557; called by muse, mutect2, varscan2
- TTN | c.73550G>A p.R24517K (on ENST00000591111; = p.R17093K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | PolyPhen benign (0); catalogued as COSV100603858, COSV60303603; called by muse, mutect2, varscan2
- TTN | c.20911G>A p.E6971K (on ENST00000591111; = p.E6044K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | PolyPhen possibly damaging (0.64); catalogued as COSV59901371; called by muse, mutect2
- UBASH3A | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145463901, COSV52313259; called by muse, mutect2, varscan2
- UBR2 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65752253, COSV65752993; called by muse, mutect2, varscan2
- UBR5 | c.7709T>G p.F2570C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55298751; called by muse, mutect2, varscan2
- UGGT1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV99390047; called by muse, mutect2, varscan2
- UGGT1 | c.2885C>T p.P962L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs754313556, COSV52140893; called by muse, mutect2, varscan2
- USH2A | c.14011G>A p.E4671K | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as rs769560933, COSV56326302; called by muse, mutect2, varscan2
- USH2A | c.4591C>T p.P1531S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as COSV56381438; called by muse, mutect2, varscan2
- VIRMA | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV52590466; called by muse, mutect2
- VPS26A | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV54967629, COSV54969381; called by muse, mutect2, varscan2
- WFDC11 | c.102G>A p.R34= | Splice Region (SNP) | VAF 65/150 reads (43%) | catalogued as COSV60975768; called by muse, mutect2, varscan2
- ZAN | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.99); catalogued as rs267601185, COSV61806569, COSV61815322; called by muse, mutect2, varscan2
- ZKSCAN1 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV60875490; called by muse, mutect2, varscan2
- ZNF354A | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 92/217 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV59984732; called by muse, mutect2, varscan2
- ZNF566 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67574616; called by muse, mutect2, varscan2
- ZPLD1 | c.623G>A p.G208E (on ENST00000466937 / NM_001329788.1; = p.G224E on NM_175056.2) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60355816, COSV99072561; called by muse, mutect2, varscan2
- NSMAF | c.1428_1437delinsTG p.V477Afs*25 | Frame Shift Del (DEL) | VAF 21/92 reads (23%) | called by pindel, varscan2*
- RBP3 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRBV20-1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRBV20-1 | c.230A>C p.E77A | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADARB2 | c.1332C>T p.F444= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV67219687; called by muse, mutect2
- ANKRD16 | c.1002T>A p.S334= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as COSV51948604; called by muse, mutect2, varscan2
- ARHGAP44 | c.474G>A p.Q158= | Silent (SNP) | VAF 11/11 reads (100%) | catalogued as rs750887287, COSV52401444; called by muse, mutect2
- ARMH4 | c.1053G>A p.E351= | Silent (SNP) | VAF 69/189 reads (37%) | catalogued as COSV99957386, COSV99959129; called by muse, mutect2, varscan2
- ATRAID | c.477C>T p.P159= (on ENST00000611786; = p.P46= on NM_016085.5) | Silent (SNP) | VAF 76/144 reads (53%) | catalogued as COSV53031258; called by muse, mutect2, varscan2
- AXL | c.885G>A p.R295= | Silent (SNP) | VAF 161/298 reads (54%) | catalogued as COSV56573955; called by muse, mutect2, varscan2
- B4GALNT3 | c.1458G>A p.L486= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as rs1369281049, COSV56757372; called by muse, mutect2, varscan2
- BMP2 | c.558C>T p.F186= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV66579190; called by muse, mutect2
- BRD2 | c.2349C>T p.S783= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as COSV66374383; called by muse, mutect2, varscan2
- C2CD3 | c.1416C>T p.V472= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs748228797, COSV58099886; called by muse, mutect2, varscan2
- C5 | c.3012C>T p.P1004= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV56331675; called by muse, mutect2, varscan2
- CCNG2 | c.591C>T p.I197= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV60354658; called by muse, mutect2, varscan2
- CDC45 | c.699C>T p.I233= | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as COSV54248256; called by muse, mutect2, varscan2
- CEACAM3 | c.165C>T p.V55= | Silent (SNP) | VAF 96/209 reads (46%) | catalogued as COSV55762632; called by muse, mutect2, varscan2
- CELSR3 | c.9033G>A p.L3011= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV51141996; called by muse, mutect2, varscan2
- CEP250 | c.4585C>T p.L1529= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV61173875; called by muse, mutect2, varscan2
- CNNM2 | c.1389C>T p.A463= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV63996403; called by muse, mutect2, varscan2
- CRB2 | c.735C>T p.F245= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV63505314; called by muse, mutect2, varscan2
- CSPG4 | c.4908G>A p.Q1636= | Silent (SNP) | VAF 70/121 reads (58%) | catalogued as COSV57900565; called by muse, mutect2, varscan2
- CYP21A2 | c.1137C>T p.I379= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100925657; called by mutect2, varscan2
- CYP4F12 | c.894C>T p.F298= | Silent (SNP) | VAF 81/178 reads (46%) | catalogued as COSV104410439, COSV61173187; called by muse, mutect2, varscan2
- DCTN2 | c.207C>T p.F69= (on ENST00000548249 / NM_001261413.2; = p.F74= on NM_006400.4) | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as rs1338351964, COSV71553310; called by muse, varscan2
- DENND6B | c.1566C>T p.I522= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs780005592, COSV100833985, COSV63784147; called by muse, mutect2, varscan2
- DPAGT1 | c.681C>T p.F227= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV53829573; called by muse, mutect2, varscan2
- DSCAM | c.780G>A p.K260= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV68034886; called by muse, mutect2, varscan2
- ELANE | c.726C>T p.I242= | Silent (SNP) | VAF 167/372 reads (45%) | catalogued as COSV55048520; called by muse, mutect2, varscan2
- FANCA | c.3690G>A p.L1230= | Silent (SNP) | VAF 64/133 reads (48%) | catalogued as rs1369764790, COSV57072795; called by muse, mutect2, varscan2
- FASLG | c.295C>T p.L99= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV60680890; called by muse, mutect2, varscan2
- FGA | c.1587C>T p.F529= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as COSV57395663, COSV57396294; called by muse, mutect2, varscan2
- FRMPD2 | c.630G>A p.R210= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs865937300, COSV59715407; called by muse, mutect2, varscan2
- FYB2 | c.1317C>T p.A439= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV58588642; called by muse, mutect2, varscan2
- GABRA3 | c.279G>A p.V93= | Silent (SNP) | VAF 36/40 reads (90%) | catalogued as COSV64804443; called by muse, mutect2, varscan2
- GLP1R | c.1329G>A p.L443= | Silent (SNP) | VAF 77/157 reads (49%) | catalogued as rs371819123; called by muse, mutect2, varscan2
- GRIN2A | c.4014G>A p.G1338= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs61758997, COSV58030294; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1266C>T p.D422= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV100736376; called by muse, mutect2, varscan2
- GUCY1A1 | c.1296G>A p.L432= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs1425370192, COSV56655822; called by muse, mutect2, varscan2
- HIVEP3 | c.3132C>T p.F1044= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV56022465, COSV56023664; called by muse, mutect2, varscan2
- IGHV3-7 | c.108C>T p.S36= | Silent (SNP) | VAF 99/267 reads (37%) | catalogued as rs113025074; called by muse, mutect2, varscan2
- IGSF21 | c.510C>T p.C170= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs749032031, COSV52142643; called by muse, mutect2, varscan2
- IPO13 | c.2337C>T p.F779= | Silent (SNP) | VAF 205/410 reads (50%) | catalogued as COSV64893523; called by muse, mutect2, varscan2
- ITIH5 | c.573C>T p.I191= | Silent (SNP) | VAF 57/98 reads (58%) | catalogued as COSV56903057, COSV56911860; called by muse, mutect2, varscan2
- LILRB5 | c.504A>C p.S168= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV60260628; called by muse, mutect2, varscan2
- LMO3 | c.183C>A p.I61= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV99662479, COSV99663018; called by muse, mutect2, varscan2
- MON1B | c.141G>A p.E47= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1452041554, COSV99941418; called by muse, mutect2, varscan2
- MPC2 | c.378C>T p.H126= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV54797576; called by muse, mutect2, varscan2
- MSLNL | c.954C>T p.F318= | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as COSV53505826; called by muse, mutect2, varscan2
- MUC16 | c.17379C>T p.I5793= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as rs763264937, COSV67489580; called by muse, mutect2, varscan2
- MUC16 | c.5985T>A p.V1995= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV67489594; called by muse, mutect2, varscan2
- MYO18B | c.1830C>T p.V610= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV59146451; called by muse, mutect2, varscan2
- NLRP7 | c.750C>T p.F250= | Silent (SNP) | VAF 76/190 reads (40%) | catalogued as rs140816006, CM115931, COSV60179531; called by muse, mutect2, varscan2
- NUP210L | c.693T>C p.V231= | Silent (SNP) | VAF 181/356 reads (51%) | catalogued as COSV55156412; called by muse, mutect2, varscan2
- OR10J3 | c.36C>T p.F12= | Silent (SNP) | VAF 94/194 reads (48%) | catalogued as COSV59955527; called by muse, mutect2
- OR10Z1 | c.879G>A p.R293= | Silent (SNP) | VAF 122/252 reads (48%) | catalogued as rs781215502, COSV63525122; called by muse, mutect2, varscan2
- OR1L6 | c.1017G>A p.K339= (on ENST00000373684; = p.K303= on NM_001004453.2) | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as rs1305352805, COSV59027810, COSV59029592; called by muse, mutect2, varscan2
- OR4N5 | c.843G>A p.L281= | Silent (SNP) | VAF 54/106 reads (51%) | catalogued as rs1016089624, COSV99048806; called by muse, mutect2, varscan2
- OR6C68 | c.621C>T p.I207= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV65563847; called by muse, mutect2, varscan2
- OR6F1 | c.771C>T p.F257= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as rs777051434, COSV57466858; called by muse, mutect2, varscan2
- OR6N1 | c.633C>T p.F211= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV58647506; called by muse, mutect2, varscan2
- OR8S1 | c.519C>T p.I173= | Silent (SNP) | VAF 61/125 reads (49%) | catalogued as COSV59599327; called by muse, mutect2, varscan2
- OR9I1 | c.912C>T p.V304= | Silent (SNP) | VAF 46/73 reads (63%) | catalogued as rs368868026, COSV56925654, COSV56925909; called by muse, mutect2, varscan2
- OSGEP | c.849G>A p.R283= | Silent (SNP) | VAF 35/55 reads (64%) | catalogued as COSV52833670; called by muse, mutect2, varscan2
- OTOGL | c.1368A>C p.S456= (on ENST00000547103; = p.S447= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV72007393; called by muse, mutect2, varscan2
- PCDH15 | c.5076G>A p.L1692= (on ENST00000644397 / NM_001354429.2; = p.L1634= on NM_001142771.2) | Silent (SNP) | VAF 111/200 reads (56%) | catalogued as rs760760757, COSV64730492; called by muse, mutect2, varscan2
- PCDH15 | c.5265G>A p.Q1755= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV64730500; called by muse, mutect2, varscan2
- PCDHA13 | c.1803G>A p.S601= | Silent (SNP) | VAF 89/95 reads (94%) | catalogued as COSV56479600; called by muse, mutect2, varscan2
- PCYOX1L | c.135C>T p.L45= | Silent (SNP) | VAF 62/65 reads (95%) | catalogued as COSV51005055; called by muse, mutect2, varscan2
- PHF6 | c.903C>T p.Y301= | Silent (SNP) | VAF 35/35 reads (100%) | catalogued as COSV59699101, COSV59706253, COSV59707174; called by muse, mutect2, varscan2
- PLCL2 | c.2989C>T p.L997= (on ENST00000615277 / NM_001144382.2; = p.L871= on NM_015184.5) | Silent (SNP) | VAF 78/184 reads (42%) | catalogued as COSV67624808; called by muse, mutect2, varscan2
- PLEK | c.333G>A p.R111= | Silent (SNP) | VAF 75/174 reads (43%) | catalogued as rs1333245905, COSV52253367, COSV52253719; called by muse, mutect2, varscan2
- PLXNA1 | c.3921C>T p.I1307= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as rs1470336344, COSV52531943; called by muse, mutect2, varscan2
- PPP6C | c.912C>T p.F304= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as rs769967971, COSV65207580; called by muse, mutect2, varscan2
- PRG3 | c.12C>T p.L4= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs775892893, COSV99755707; called by muse, varscan2
- PRPF18 | c.24C>T p.I8= | Silent (SNP) | VAF 88/153 reads (58%) | catalogued as COSV60726129; called by muse, mutect2, varscan2
- PSMB1 | c.4T>C p.L2= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV51531860; called by muse, mutect2, varscan2
- PXDN | c.3063C>T p.I1021= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as COSV53236739; called by muse, mutect2, varscan2
- RASSF9 | c.486G>A p.R162= | Silent (SNP) | VAF 64/146 reads (44%) | catalogued as COSV63433229; called by muse, mutect2, varscan2
- RFT1 | c.514C>T p.L172= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV56250122; called by muse, mutect2, varscan2
- RHO | c.810C>T p.S270= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs768210562, CM010130, COSV56214527; called by muse, mutect2, varscan2
- RNFT2 | c.822C>T p.T274= | Silent (SNP) | VAF 63/120 reads (53%) | catalogued as COSV57483792, COSV57489810; called by muse, mutect2, varscan2
- SEC16A | c.3558C>G p.L1186= | Silent (SNP) | VAF 35/37 reads (95%) | catalogued as rs748142002, COSV51539381; called by muse, mutect2, varscan2
- SH2D5 | c.1002G>A p.V334= (on ENST00000444387 / NM_001103161.2; = p.V250= on NM_001103160.2) | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV56121945; called by muse, mutect2
- SIRT6 | c.273C>T p.P91= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100511089; called by muse, mutect2, varscan2
- SLAMF7 | c.708C>T p.L236= | Silent (SNP) | VAF 95/198 reads (48%) | catalogued as rs144271994; called by muse, mutect2, varscan2
- SLC44A5 | c.513G>A p.A171= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs762534368, COSV63762599; called by muse, mutect2, varscan2
- SLC45A3 | c.1521C>T p.S507= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV65655450; called by muse, mutect2, varscan2
- SLC8A1 | c.762G>A p.R254= | Silent (SNP) | VAF 52/105 reads (50%) | catalogued as rs1184259599, COSV60494762; called by muse, mutect2, varscan2
- TIPIN | c.441C>T p.L147= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs777716272, COSV56020921; called by muse, mutect2, varscan2
- TNRC18 | c.5340G>A p.R1780= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV101269468, COSV68163875; called by muse, mutect2, varscan2
- TPTE | c.1299C>T p.I433= (on ENST00000618007 / NM_199261.4; = p.I415= on NM_199259.4) | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1261831537; called by muse, mutect2
- TRPV5 | c.855C>T p.S285= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV54689349; called by muse, mutect2, varscan2
- TTN | c.53550G>A p.E17850= (on ENST00000591111; = p.E10426= on NM_003319.4) | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV60303689; called by muse, mutect2, varscan2
- TTN | c.22026C>T p.F7342= (on ENST00000591111; = p.F6415= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV100636082, COSV60181547; called by muse, mutect2, varscan2
- UGGT1 | c.615G>A p.E205= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV99390044; called by muse, mutect2, varscan2
- USP20 | c.87C>T p.T29= | Silent (SNP) | VAF 136/146 reads (93%) | catalogued as COSV59618485; called by muse, mutect2
- VPS35L | c.186C>T p.S62= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as COSV51990443; called by muse, mutect2, varscan2
- WFDC8 | c.519C>T p.I173= | Silent (SNP) | VAF 46/89 reads (52%) | catalogued as COSV51490426; called by muse, mutect2, varscan2
- XDH | c.780G>A p.G260= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV65150946; called by muse, mutect2, varscan2
- XIRP2 | c.3225G>A p.K1075= (on ENST00000628543; = p.K1250= on NM_152381.6) | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as rs750084112, COSV54730449; called by muse, mutect2, varscan2
- ZFP64 | c.1098C>T p.C366= | Silent (SNP) | VAF 84/171 reads (49%) | catalogued as COSV53803373; called by muse, mutect2, varscan2
- ZNF233 | c.123C>T p.F41= | Silent (SNP) | VAF 78/193 reads (40%) | catalogued as COSV61934616; called by muse, mutect2, varscan2
- ZNF343 | c.1185C>T p.T395= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV53855391; called by muse, mutect2, varscan2
- ZNF516 | c.2559C>T p.P853= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as COSV71587575; called by muse, mutect2, varscan2
- ZNF710 | c.1251C>T p.S417= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs766583293, COSV51565332; called by muse, mutect2, varscan2
- ZNF831 | c.2367C>T p.A789= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV64044653; called by muse, mutect2, varscan2
- ZPLD1 | c.1122G>A p.L374= (on ENST00000466937 / NM_001329788.1; = p.L390= on NM_175056.2) | Silent (SNP) | VAF 123/233 reads (53%) | catalogued as COSV60355823; called by muse, mutect2, varscan2
- C3P1 | n.3045G>A | RNA (SNP) | VAF 35/106 reads (33%) | called by muse, mutect2, varscan2
- IGHG1 | chr14:105737826 G>A | 3'Flank (SNP) | VAF 86/221 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.34264+5498G>A | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100587869; called by muse, mutect2, varscan2
- TTN | c.10360+2508G>A | Intron (SNP) | VAF 4/13 reads (31%) | catalogued as rs866726793, COSV60018777; called by muse, mutect2, varscan2
- TTN | c.10360+1559G>A | Intron (SNP) | VAF 44/91 reads (48%) | catalogued as rs756398618, COSV100587871; called by muse, mutect2, varscan2
- TTN | c.10303+2215G>A | Intron (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100587872; called by muse, mutect2, varscan2
